Surgical pathology report (de-identified scan), TCGA case TCGA-77-6845, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-6845-01A (Primary Tumor).

HISTORY

Right middle lobectomy. Adherent to pericardium. [REDACTED]

MACROSCOPIC

Two specimens received.

1: The first specimen is labelled "right middle lobe" and consists of a piece of lung measuring 123 x 100 x 55 mm and weighing 232 g. An amount of fat and pericardium is adherent to one surface while the pleura on the opposite side appears puckered. On sectioning a large tumour mass measuring approximately 53 x 45 x 57 mm is seen. This is approximately 11 mm away from the bronchial resection margin and extends through most of the specimen. The tumour has a yellow nodular surface with a central necrotic area. The tumour is approximately 1 mm away from opposing pleural surfaces and 2 mm away from the pleural margin opposite the bronchial resection margin. The tumour extends to the area underlying the pericardium and fat and on sectioning appears to invade into the pericardium and fat. [Bronchial resection margin, 1A; tumour near bronchial resection margin, 1B; tumour and opposite pleural resection margin, 1C; tumour with superior pleura, 1D; tumour and opposing pleural surface, 1E; tumour with presumed involvement of overlying pericardium, 1F; tumour involving overlying fat, 1G; further section through tumour with overlying pericardium, 1H; tumour extending into fatty tissue, 1I; normal uninvolved lung parenchyma, 1J.]

2: The second specimen is labelled "hilar lymph node right" and consists of two fragments of blackish tissue measuring in aggregate 10 x 5 x 3 mm. [Wrapped and blocked in toto, 2A]

[REDACTED]

MICROSCOPIC

1: Sections show a moderately differentiated squamous cell carcinoma with extensive central necrosis. Origin from a bronchus is not identified, and several bronchi within the tumour show no evidence of squamous metaplasia or dysplasia. The bronchial resection margin is clear of malignancy and shows no evidence of squamous metaplasia or dysplasia. Tumour is confirmed to invade into the pericardium but does not extend through to the inner mesothelial-lined surface and is clear of the adjacent soft tissue resection margins. There is no evidence of pleural invasion on the opposite aspect of the specimen to the adherent pericardium. Vascular, lymphatic and perineural invasion is present. Distant lung parenchyma shows mild centriacinar emphysema.

2: Sections show fragments of anthracotic lymph node in which there are silicotic nodules but no evidence of metastatic carcinoma.

SUMMARY

Right middle lobectomy and right-lymph node:

Moderately differentiated squamous cell carcinoma, 57 mm in greatest dimension.

Vascular, lymphatic, perineural and pericardial invasion present.

No lymph node metastases.

Pathological stage T3 N0.

[REDACTED]

T-28000 M-80703 P1-03000

Source: NCI Genomic Data Commons file 34ab4dec-c8e1-4411-a7a0-595a2086358b (TCGA-77-6845.105EAA92-2EBD-4A99-A01C-88816A776F49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).